Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7374, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7374-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) LARYNX, SUPRAGLOTTIC, BIOPSY: MODERATELY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA.

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: Dr. [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) Supraglottic lesion

GROSS DESCRIPTION:

1) SOURCE: Supraglottic Lesion

Received fresh, labeled "supraglottic lesion" are 3 portions of soft, pink, and hemorrhagic mucosa measuring in aggregate 9.0 x 6.0 x 4.0 mm. The specimen is submitted entirely in a teabag following frozen section.

Summary of sections: 1AFSC, 3/1.

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Supraglottic Lesion

FROZEN SECTION DIAGNOSIS: SQUAMOUS CELL CARCINOMA. GG/KE

Electronically signed by: [REDACTED]

Source: NCI Genomic Data Commons file ba68e089-efe5-4814-a492-c19d08d5e302 (TCGA-CR-7374.46BF6546-863D-42C4-A0CB-83710DED8925.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).